Surgical pathology report (de-identified scan), TCGA case TCGA-EL-A3GQ, project TCGA-THCA (Thyroid Carcinoma), tissue source site MD Anderson, specimen TCGA-EL-A3GQ-01A (Primary Tumor).

	Yes	No

Pathology Report

DOB:
Physician:

Sex: F

Collected:

Accession:

Received:

Case type: Surgical Case

DIAGNOSIS

(A) TOTAL THYROIDECTOMY:

PAPILLARY THYROID CARCINOMA, FOLLICULAR VARIANT

Location: Right lobe

Multi-focal: No

Size = 1.3 cm

Extrathyroidal extension: Absent

Lymphovascular invasion: Absent

Resection Margins: Negative

Background Thyroid: Multinodular adenomatous goiter

Lymph nodes:

No tumor present in 1 lymph nodes

ICD-0-3

carcinoma, papillary, follicular variant
8340/3

Site: thyroid, NOS 873.9

lw
11/30/11

GROSS DESCRIPTION

(A) TOTAL THYROIDECTOMY – A thyroidectomy with right lobe (4.0 x 2.0 x 1.0 cm) and left lobe (3.0 x 1.5 x 0.5 cm) shows a smooth surface. Within the inferior aspect of the right lobe a partially circumscribes soft pink nodule (1.3 x 1.0 x 0.7 cm) appear partially encapsulated with portion of rim of calcification and secondary nodule outside of this area. The left lobe is unremarkable.

SECTION CODE: A1, A2, sections of left thyroid lobe from superior-to-inferior; A3, section of isthmus; A4, right unremarkable upper lobe; A5, A6, right-sided nodule.

CLINICAL HISTORY

None given.

SNOMED CODES

T-B6000, T-C4200, M-83403, M-Y3420

"Some tests reported here may have been developed and performance characteristics determined by:
These tests have not been specifically cleared or approved by the U.S. Food and Drug Administration."

Entire report and diagnosis completed by:

Source: NCI Genomic Data Commons file 80600345-57a7-488c-b991-1be2a3c685ba (TCGA-EL-A3GQ.FB308CCC-CB34-4357-84FB-6EA680C7F9B9.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).